CPTAC case C3L-03632 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1309999e-853f-4f99-84a2-1095e674f5ae

Demographics
Sex at birth: male; Year of birth: 1944; Vital status: Dead; Days to death: 1,481 days (4.1 years); Year of death: 2022; Cause of death: Cancer Related.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; Age at diagnosis: 74.1 years (27,050 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,481 days (4.1 years); Progression or recurrence: no; Days to last follow up: 1,481 days (4.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.1 cm (a second GDC size field records 12 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 12; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: No.

Follow-up (5 entries)
- Days to follow up: 330 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 736 days (2.0 years); Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,121 days (3.1 years); Disease response: Stable Disease; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,439 days (3.9 years); Disease response: Progressive Disease; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 1,481 days (4.1 years); Disease response: Progressive Disease; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 77 kg; Height: 172 cm; BMI: 26.03.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03632-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 134.8 mg; Time between excision and freezing: 48 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03632-27: Section location: Uncinate process; Percent tumor nuclei: 20; Percent necrosis: 0.
- Sample C3L-03632-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 76.8 mg; Time between excision and freezing: 48 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03632-28: Section location: Uncinate process; Percent tumor nuclei: 30; Percent necrosis: 0.
- Sample C3L-03632-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
